Somatic mutation profile of tumor specimen ALCH-B2QJ-TTP1-A (aliquot ALCH-B2QJ-TTP1-A-1-0-D-A77Z-36) from ALCHEMIST case ALCH-B2QJ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 67.8 years (24,778 days).
Specimen ALCH-B2QJ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7af93a8d-6c63-4059-9d9f-9fe3c996c730.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2QJ-NB1-A (Blood Derived Normal), aliquot ALCH-B2QJ-NB1-A-1-0-D-A77Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/65c629f2-d671-430b-bf7e-ec9763eb06c9

The open-access MAF lists 278 somatic variants for this specimen: 186 protein-altering or splice-affecting, 56 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 160, Silent 56, Intron 20, Nonsense Mutation 8, 3'UTR 6, Frame Shift Del 6, Splice Site 6, RNA 5, 5'Flank 3, Splice Region 2, Frame Shift Ins 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PCDH12 | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 28/77 reads (36%) | catalogued as rs370283860; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 171/260 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ABCA7 | c.1271G>T p.R424L | Missense Mutation (SNP) | VAF 54/185 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs765604779; called by muse, mutect2, varscan2
- ADCY8 | c.1507G>T p.D503Y | Missense Mutation (SNP) | VAF 129/290 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53903301, COSV99651047; called by muse, mutect2, varscan2
- ANKRD60 | c.702T>A p.D234E | Missense Mutation (SNP) | VAF 79/175 reads (45%) | SIFT tolerated (0.73); PolyPhen benign (0.067); catalogued as rs1423414971; called by muse, mutect2, varscan2
- APOB | c.8906G>C p.R2969T | Missense Mutation (SNP) | VAF 40/244 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs768963343, COSV51933557; called by muse, mutect2, varscan2
- BEND7 | c.245G>T p.R82L | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61991222; called by mutect2, varscan2
- BMPER | c.874C>T p.R292* | Nonsense Mutation (SNP) | VAF 69/603 reads (11%) | catalogued as rs144985513; called by muse, mutect2, varscan2
- C10orf71 | c.4114G>A p.A1372T | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1299538540; called by muse, mutect2, varscan2
- C2CD6 | c.1642G>C p.V548L | Missense Mutation (SNP) | VAF 45/191 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.097); catalogued as COSV53800749; called by muse, mutect2, varscan2
- CDH2 | c.1157C>T p.T386M | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.068); catalogued as rs764389179, COSV52272499, COSV52293297; called by muse, mutect2, varscan2
- CHRD | c.1720C>T p.L574F | Missense Mutation (SNP) | VAF 20/536 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52610846; called by muse, mutect2
- COL11A1 | c.2627C>A p.P876Q | Missense Mutation (SNP) | VAF 170/464 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1181587428; called by muse, mutect2, varscan2
- CPM | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 54/244 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV58035036; called by muse, mutect2, varscan2
- CSMD3 | c.3461G>C p.R1154T (on ENST00000297405 / NM_001363185.1; = p.R1050T on NM_052900.3) | Missense Mutation (SNP) | VAF 72/474 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.403); catalogued as COSV52121610, COSV99823750; called by muse, mutect2, varscan2
- CUL9 | c.1220G>T p.R407L | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as COSV52733813; called by muse, mutect2, varscan2
- F13A1 | c.1556T>C p.V519A | Missense Mutation (SNP) | VAF 102/385 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs1224605741; called by muse, mutect2, varscan2
- FAM135B | c.596G>T p.G199V | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.141); catalogued as COSV52702509, COSV52723712; called by muse, mutect2, varscan2
- FANCM | c.1682T>G p.F561C | Missense Mutation (SNP) | VAF 31/277 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1340057261; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.872A>G p.Y291C | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as rs758188248; called by muse, mutect2, varscan2
- GABRA2 | c.1018A>G p.R340G | Missense Mutation (SNP) | VAF 93/270 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100734635; called by muse, mutect2, varscan2
- GCM1 | c.1105C>T p.H369Y | Missense Mutation (SNP) | VAF 74/270 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.185); catalogued as COSV52520657; called by muse, mutect2, varscan2
- GPC2 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52783809; called by muse, mutect2, varscan2
- GRM6 | c.1778C>A p.A593D | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV51445033; called by muse, mutect2, varscan2
- IGHV1-46 | c.230C>G p.T77R | Missense Mutation (SNP) | VAF 243/418 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as rs1555524753; called by muse, mutect2, varscan2
- KCNB2 | c.2490C>A p.S830R | Missense Mutation (SNP) | VAF 58/188 reads (31%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.055); catalogued as rs756573146; called by muse, mutect2, varscan2
- KCNK18 | c.679C>A p.L227M | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.218); catalogued as COSV100572148; called by muse, mutect2, varscan2
- LRP8 | c.1331G>C p.R444P | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV60101559; called by muse, mutect2, varscan2
- LRRC18 | c.616C>G p.L206V | Missense Mutation (SNP) | VAF 43/358 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.114); catalogued as COSV53281835; called by muse, mutect2, varscan2
- MDGA2 | c.2242G>A p.G748R (on ENST00000399232 / NM_001113498.2; = p.G450R on NM_182830.4) | Missense Mutation (SNP) | VAF 62/135 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.749); catalogued as COSV62115779; called by muse, mutect2, varscan2
- MGAT4B | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as rs932687966; called by muse, mutect2, varscan2
- MMAA | c.313A>G p.I105V | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.654); catalogued as rs1284134117; called by muse, varscan2
- MUC12 | c.14452A>T p.T4818S (on ENST00000379442; = p.T4675S on NM_001164462.1) | Missense Mutation (SNP) | VAF 113/373 reads (30%) | SIFT deleterious, low confidence (0.03); catalogued as rs1213353645; called by muse, mutect2, varscan2
- MYO16 | c.1382C>A p.S461Y | Missense Mutation (SNP) | VAF 72/137 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as COSV51784348; called by muse, mutect2, varscan2
- MYT1 | c.1059C>A p.D353E | Missense Mutation (SNP) | VAF 90/211 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as COSV60508740; called by muse, mutect2, varscan2
- NF1 | c.2991-1G>T p.X997_splice | Splice Site (SNP) | VAF 78/237 reads (33%) | catalogued as CS000875, CS1311521, CS961633, COSV62210968; called by muse, mutect2, varscan2
- NKAPD1 | c.821G>A p.R274H (on ENST00000280352 / NM_001082970.2; = p.R275H on NM_018195.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs201262827, COSV54777523; called by muse, mutect2, varscan2
- NPAP1 | c.1486G>T p.D496Y | Missense Mutation (SNP) | VAF 60/90 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100275170; called by muse, mutect2, varscan2
- OR4C46 | c.672G>C p.R224S | Missense Mutation (SNP) | VAF 44/199 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.279); catalogued as COSV60218882; called by muse, mutect2, varscan2
- OR5H15 | c.742G>C p.V248L | Missense Mutation (SNP) | VAF 35/291 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764492516; called by muse, mutect2, varscan2
- PCDH10 | c.1217A>G p.K406R | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.997); catalogued as COSV52093599; called by muse, mutect2, varscan2
- PCDH11X | c.2630C>A p.S877Y | Missense Mutation (SNP) | VAF 102/255 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV53450226; called by muse, varscan2
- PKD1 | c.12763C>T p.P4255S (on ENST00000262304 / NM_001009944.3; = p.P4254S on NM_000296.4) | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as CM021658; called by muse, mutect2, varscan2
- PTH2 | c.10del p.R4Afs*84 | Frame Shift Del (DEL) | VAF 28/93 reads (30%) | catalogued as rs1318916199; called by pindel, varscan2
- PWP1 | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 67/280 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as rs773941925; called by muse, mutect2, varscan2
- ROR2 | c.2014C>T p.R672W | Missense Mutation (SNP) | VAF 35/185 reads (19%) | catalogued as rs760064804; called by muse, mutect2, varscan2
- SCN1A | c.696C>A p.G232= | Splice Region (SNP) | VAF 31/107 reads (29%) | catalogued as rs752978101; called by muse, mutect2, varscan2
- SDCCAG8 | c.1018G>T p.V340L | Missense Mutation (SNP) | VAF 111/189 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1308863502; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SFMBT2 | c.2369C>A p.A790E | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.025); catalogued as COSV100738493; called by muse, mutect2
- SFRP4 | c.919C>A p.R307S | Missense Mutation (SNP) | VAF 54/228 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV71412432; called by muse, mutect2, varscan2
- SLC26A3 | c.1078G>A p.V360I | Missense Mutation (SNP) | VAF 46/336 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as rs565092091, COSV60640068; called by muse, mutect2, varscan2
- SLC26A4 | c.998G>C p.R333T | Missense Mutation (SNP) | VAF 60/203 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as COSV55917423; called by muse, mutect2, varscan2
- SLCO1B1 | c.297C>G p.I99M | Missense Mutation (SNP) | VAF 74/251 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV57013761; called by muse, varscan2
- SNX19 | c.1988G>A p.R663H | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs753108394; called by muse, mutect2, varscan2
- SORCS3 | c.1028G>T p.W343L | Missense Mutation (SNP) | VAF 55/221 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100864210; called by muse, mutect2, varscan2
- SPAG6 | c.107C>T p.T36M | Missense Mutation (SNP) | VAF 114/321 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as COSV57617789; called by muse, mutect2, varscan2
- STXBP4 | c.1582G>T p.V528L | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV64467535; called by muse, mutect2, varscan2
- SYNPO2 | c.1288G>T p.E430* | Nonsense Mutation (SNP) | VAF 78/165 reads (47%) | catalogued as COSV61109730; called by muse, mutect2, varscan2
- TMEM132D | c.1381G>A p.G461S | Missense Mutation (SNP) | VAF 52/227 reads (23%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.962); catalogued as rs1410065607; called by muse, mutect2, varscan2
- TMEM250 | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1421508943; called by muse, mutect2, varscan2
- TSHZ3 | c.1315G>C p.D439H | Missense Mutation (SNP) | VAF 7/201 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV53674019, COSV53680200; called by muse, mutect2
- TTLL2 | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.148); catalogued as rs571140155, COSV99515009; called by muse, mutect2, varscan2
- TTN | c.48775G>C p.E16259Q (on ENST00000591111; = p.E8835Q on NM_003319.4) | Missense Mutation (SNP) | VAF 8/144 reads (6%) | PolyPhen possibly damaging (0.856); catalogued as rs1231539821, COSV59934261; called by muse, mutect2
- TTN | c.21692G>C p.W7231S (on ENST00000591111; = p.W6304S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/86 reads (36%) | PolyPhen probably damaging (1); catalogued as rs1207359424; called by muse, mutect2, varscan2
- XIRP2 | c.6379G>A p.A2127T (on ENST00000628543; = p.A2302T on NM_152381.6) | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.023); catalogued as COSV54700151; called by muse, mutect2, varscan2
- ZNF438 | c.895A>G p.R299G | Missense Mutation (SNP) | VAF 56/256 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs749733480; called by muse, mutect2, varscan2
- ABCC5 | c.3982G>C p.D1328H | Missense Mutation (SNP) | VAF 362/588 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- ACAN | c.329C>G p.P110R | Missense Mutation (SNP) | VAF 106/419 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADCY1 | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- ANOS1 | c.1882A>C p.T628P | Missense Mutation (SNP) | VAF 151/275 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- APBB3 | c.827G>T p.R276L (on ENST00000357560 / NM_133173.2; = p.R283L on NM_006051.3) | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARAP1 | c.510-1G>T p.X170_splice | Splice Site (SNP) | VAF 103/194 reads (53%) | called by muse, mutect2, varscan2
- ATF5 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, varscan2
- CCDC102B | c.137T>C p.L46P | Missense Mutation (SNP) | VAF 163/702 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC102B | c.607-1G>T p.X203_splice | Splice Site (SNP) | VAF 34/122 reads (28%) | called by muse, mutect2
- CCDC185 | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated (0.28); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- CES5A | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP54 | c.7002G>T p.Q2334H | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- CFD | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.95); PolyPhen benign (0.003); called by muse, mutect2
- CLC | c.391T>G p.S131A | Missense Mutation (SNP) | VAF 70/333 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- CLEC4D | c.350C>A p.A117D | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- CLOCK | c.1449G>T p.Q483H | Missense Mutation (SNP) | VAF 75/202 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CLTC | c.4864G>A p.E1622K | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, varscan2
- CLVS1 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- COL11A1 | c.2626C>A p.P876T | Missense Mutation (SNP) | VAF 165/457 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- COMMD5 | c.211C>T p.L71F | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPS1 | c.62C>A p.T21N | Missense Mutation (SNP) | VAF 73/203 reads (36%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CSMD3 | c.8960T>C p.L2987S (on ENST00000297405 / NM_001363185.1; = p.L2818S on NM_052900.3) | Missense Mutation (SNP) | VAF 60/250 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTNNA3 | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.587); called by muse, mutect2
- CUBN | c.3598G>C p.G1200R | Missense Mutation (SNP) | VAF 86/412 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP4A22 | c.776C>A p.A259D | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- DACH2 | c.1377G>T p.L459F | Missense Mutation (SNP) | VAF 57/102 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DGKI | c.2986G>A p.E996K | Missense Mutation (SNP) | VAF 59/212 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- DHX37 | c.1130G>A p.R377K | Missense Mutation (SNP) | VAF 21/236 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2
- DLD | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 43/415 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAH6 | c.10051C>A p.L3351I | Missense Mutation (SNP) | VAF 58/220 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- DPPA2 | c.850A>C p.K284Q | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- DUSP11 | c.907C>T p.Q303* | Nonsense Mutation (SNP) | VAF 43/125 reads (34%) | called by muse, mutect2, varscan2
- ELOA3D | c.1129C>A p.R377S | Missense Mutation (SNP) | VAF 115/2549 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2
- FAP | c.2191G>T p.D731Y | Missense Mutation (SNP) | VAF 95/312 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBH1 | c.2901G>C p.Q967H (on ENST00000362091 / NM_178150.3; = p.Q1018H on NM_032807.4) | Missense Mutation (SNP) | VAF 66/228 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- FNDC4 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FRS3 | c.49C>T p.H17Y | Missense Mutation (SNP) | VAF 68/238 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GABBR1 | c.1019G>T p.R340L | Missense Mutation (SNP) | VAF 48/218 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- GCGR | c.960C>A p.F320L | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GOLGA6L7 | c.266A>T p.Q89L | Missense Mutation (SNP) | VAF 572/711 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GOLGA8S | c.760C>A p.Q254K | Missense Mutation (SNP) | VAF 38/723 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.29); called by muse, mutect2
- GPR158 | c.2029G>C p.D677H | Missense Mutation (SNP) | VAF 56/228 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- GRIA1 | c.1324C>A p.L442M | Missense Mutation (SNP) | VAF 39/318 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- GRIA3 | c.136C>A p.Q46K | Missense Mutation (SNP) | VAF 107/192 reads (56%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HSD17B3 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 81/231 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HUS1B | c.271del p.A91Rfs*10 | Frame Shift Del (DEL) | VAF 22/87 reads (25%) | called by mutect2, pindel, varscan2
- HYDIN | c.6221C>A p.A2074D | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IGKV1-12 | c.149del p.G50Vfs*6 | Frame Shift Del (DEL) | VAF 25/193 reads (13%) | called by mutect2, varscan2
- IGSF8 | c.869G>A p.R290K | Missense Mutation (SNP) | VAF 36/49 reads (73%) | SIFT tolerated (0.57); PolyPhen benign (0.115); called by muse, varscan2
- IL3RA | c.1128del p.T378Lfs*39 | Frame Shift Del (DEL) | VAF 42/163 reads (26%) | called by mutect2, pindel, varscan2
- ISL1 | c.285_286insT p.R96Sfs*158 | Frame Shift Ins (INS) | VAF 38/235 reads (16%) | called by mutect2, pindel, varscan2
- ITFG1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 14/95 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ITIH2 | c.887T>C p.V296A | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- ITK | c.1006T>A p.Y336N | Missense Mutation (SNP) | VAF 52/383 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- KALRN | c.2165+5G>C | Splice Region (SNP) | VAF 138/256 reads (54%) | called by muse, mutect2, varscan2
- KLRC2 | c.188-2A>T p.X63_splice | Splice Site (SNP) | VAF 95/633 reads (15%) | called by muse, mutect2, varscan2
- LRIG2 | c.3079G>T p.G1027C | Missense Mutation (SNP) | VAF 151/358 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- MAN2A1 | c.2813A>G p.Q938R | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MAP4K3 | c.1427C>T p.P476L | Missense Mutation (SNP) | VAF 112/353 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- MARVELD3 | c.1043G>A p.G348D | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MCF2 | c.1669A>T p.N557Y | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- MFSD4B | c.27+1G>T p.X9_splice | Splice Site (SNP) | VAF 8/111 reads (7%) | called by muse, mutect2
- MROH2B | c.4300C>A p.L1434M | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MTUS2 | c.345G>T p.E115D | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MUC4 | c.6107C>T p.T2036I | Missense Mutation (SNP) | VAF 41/613 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.517); called by muse, mutect2
- NAV3 | c.2168C>A p.T723K | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NCOA2 | c.3410A>G p.Y1137C | Missense Mutation (SNP) | VAF 110/415 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- NFATC2 | c.1958C>T p.P653L | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- NFE2L3 | c.334C>A p.L112M | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- NPY5R | c.1021C>A p.P341T | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- NPY5R | c.1022C>A p.P341H | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- NTRK2 | c.2469G>T p.*823Yext*17 (on ENST00000323115 / NM_001369534.1; = p.*839Yext*17 on NM_006180.6 and 1 other RefSeq transcript) | Nonstop Mutation (SNP) | VAF 130/499 reads (26%) | called by muse, mutect2, varscan2
- OR10A5 | c.788C>G p.P263R | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- OR12D3 | c.357C>A p.D119E | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2AG2 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- OR2L5 | c.553A>G p.T185A | Missense Mutation (SNP) | VAF 135/252 reads (54%) | SIFT tolerated (0.24); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- OR4C11 | c.415T>A p.C139S | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR4F6 | c.493G>C p.D165H | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OR8S1 | c.814T>A p.F272I | Missense Mutation (SNP) | VAF 51/230 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- PCDH11X | c.2632C>A p.P878T | Missense Mutation (SNP) | VAF 104/256 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, varscan2
- PCDH18 | c.1168G>A p.G390R | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH7 | c.2022G>C p.M674I | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PCDHGA3 | c.1730T>A p.L577Q | Missense Mutation (SNP) | VAF 87/285 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PDILT | c.158T>A p.L53Q | Missense Mutation (SNP) | VAF 34/195 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PEX1 | c.3593C>A p.A1198E | Missense Mutation (SNP) | VAF 16/465 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.186); called by muse, mutect2
- PIF1 | c.1475G>A p.G492D | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PKD1L2 | c.1501G>A p.G501R | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- POTEC | c.515A>G p.Q172R | Missense Mutation (SNP) | VAF 67/166 reads (40%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- POTEI | c.2170G>T p.D724Y | Missense Mutation (SNP) | VAF 33/298 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- PPP1R26 | c.2135G>A p.R712K | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- RAPGEF6 | c.3007C>T p.Q1003* | Nonsense Mutation (SNP) | VAF 37/158 reads (23%) | called by muse, mutect2, varscan2
- RBM39 | c.1525_1529del p.P509Lfs*7 (on ENST00000253363 / NM_001323424.2; = p.P503Lfs*7 on NM_004902.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 21/144 reads (15%) | called by mutect2, pindel, varscan2
- RBMXL2 | c.353C>A p.P118Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RELN | c.1047G>C p.L349F | Missense Mutation (SNP) | VAF 135/560 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RNF113B | c.140G>T p.S47I | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- ROBO4 | c.2892G>A p.M964I | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- RREB1 | c.2732A>G p.Q911R | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SDCCAG8 | c.1017G>C p.Q339H | Missense Mutation (SNP) | VAF 110/189 reads (58%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SELENOT | c.43G>C p.V15L | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- SKIDA1 | c.2066T>C p.V689A | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- SLC24A1 | c.1081C>A p.P361T | Missense Mutation (SNP) | VAF 144/567 reads (25%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC30A1 | c.1061G>C p.R354T | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2
- SPANXN3 | c.358G>T p.G120* | Nonsense Mutation (SNP) | VAF 36/62 reads (58%) | called by muse, mutect2, varscan2
- SPINK5 | c.1527A>G p.I509M | Missense Mutation (SNP) | VAF 70/423 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SVEP1 | c.7018A>T p.T2340S | Missense Mutation (SNP) | VAF 49/260 reads (19%) | SIFT tolerated (0.89); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TCAF1 | c.2261del p.G754Afs*62 | Frame Shift Del (DEL) | VAF 26/86 reads (30%) | called by mutect2, varscan2
- TECPR1 | c.2690+1G>T p.X897_splice | Splice Site (SNP) | VAF 24/72 reads (33%) | called by muse, mutect2, varscan2
- TNNI2 | c.453G>C p.K151N | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- TRAF5 | c.873G>T p.E291D | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- TRBV27 | c.55dup p.L19Pfs*31 | Frame Shift Ins (INS) | VAF 5/22 reads (23%) | called by mutect2, pindel, varscan2
- TRDN | c.803C>A p.A268E | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM64 | c.289G>T p.E97* | Nonsense Mutation (SNP) | VAF 51/217 reads (24%) | called by muse, mutect2, varscan2
- TTN | c.11591C>A p.T3864N (on ENST00000591111; = p.T3818N on NM_003319.4) | Missense Mutation (SNP) | VAF 40/171 reads (23%) | called by muse, mutect2, varscan2
- TTN | c.796C>A p.P266T | Missense Mutation (SNP) | VAF 141/568 reads (25%) | PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TYW1B | c.1108G>T p.E370* | Nonsense Mutation (SNP) | VAF 40/165 reads (24%) | called by mutect2, varscan2
- ULBP3 | c.500G>T p.R167M | Missense Mutation (SNP) | VAF 107/343 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- USH2A | c.11632C>A p.L3878M | Missense Mutation (SNP) | VAF 160/268 reads (60%) | SIFT tolerated (0.14); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- WHAMM | c.991A>T p.T331S | Missense Mutation (SNP) | VAF 57/182 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- XPOT | c.2645T>C p.L882S | Missense Mutation (SNP) | VAF 65/307 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- ZNF121 | c.318T>G p.N106K | Missense Mutation (SNP) | VAF 83/280 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ACAN | c.1588C>A p.R530= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs777066916, COSV61359181; called by mutect2, varscan2
- ATCAY | c.318G>A p.S106= | Silent (SNP) | VAF 35/87 reads (40%) | catalogued as rs780287970; called by muse, mutect2, varscan2
- C6 | c.69C>T p.F23= | Silent (SNP) | VAF 64/436 reads (15%) | catalogued as COSV54705890, COSV99667070; called by muse, mutect2
- CA3 | c.6C>A p.A2= | Silent (SNP) | VAF 63/304 reads (21%) | called by muse, mutect2, varscan2
- CBLN2 | c.471C>A p.T157= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as rs781570135, COSV54050896, COSV54052702; called by muse, mutect2, varscan2
- CDHR2 | c.510T>A p.T170= | Silent (SNP) | VAF 15/64 reads (23%) | called by muse, mutect2, varscan2
- CHL1 | c.2790C>T p.D930= (on ENST00000397491 / NM_001253387.1; = p.D946= on NM_006614.4) | Silent (SNP) | VAF 28/102 reads (27%) | called by muse, mutect2, varscan2
- CNTLN | c.3693A>G p.V1231= | Silent (SNP) | VAF 42/98 reads (43%) | catalogued as rs1319347268; called by muse, mutect2, varscan2
- DEFA4 | c.111A>C p.P37= | Silent (SNP) | VAF 56/122 reads (46%) | called by muse, mutect2, varscan2
- ENO4 | c.1704G>A p.E568= (on ENST00000622726; = p.E565= on NM_001242699.2) | Silent (SNP) | VAF 29/90 reads (32%) | called by muse, mutect2, varscan2
- EP400 | c.7932G>T p.P2644= | Silent (SNP) | VAF 44/143 reads (31%) | called by muse, mutect2, varscan2
- EPRS1 | c.2820A>G p.A940= | Silent (SNP) | VAF 113/192 reads (59%) | called by muse, mutect2, varscan2
- FAT3 | c.9963C>A p.L3321= | Silent (SNP) | VAF 26/416 reads (6%) | called by muse, mutect2
- FNDC7 | c.306C>T p.S102= | Silent (SNP) | VAF 70/138 reads (51%) | called by muse, mutect2, varscan2
- FSCN3 | c.1125A>G p.P375= | Silent (SNP) | VAF 14/48 reads (29%) | called by muse, varscan2
- GALNT17 | c.1770G>A p.R590= | Silent (SNP) | VAF 51/185 reads (28%) | called by muse, mutect2, varscan2
- GGN | c.1338G>A p.P446= | Silent (SNP) | VAF 67/291 reads (23%) | catalogued as rs1305083025; called by muse, mutect2, varscan2
- GJA5 | c.393A>G p.A131= | Silent (SNP) | VAF 251/442 reads (57%) | called by muse, mutect2, varscan2
- GTSF1 | c.33T>C p.P11= | Silent (SNP) | VAF 47/254 reads (19%) | catalogued as COSV59939465; called by muse, mutect2, varscan2
- HCN1 | c.147C>A p.G49= | Silent (SNP) | VAF 49/98 reads (50%) | called by muse, mutect2, varscan2
- IPCEF1 | c.1020A>G p.R340= | Silent (SNP) | VAF 5/56 reads (9%) | called by muse, mutect2, varscan2
- JMY | c.2427A>G p.P809= | Silent (SNP) | VAF 10/67 reads (15%) | called by muse, varscan2
- KCNG2 | c.1002G>A p.A334= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs769554137; called by muse, mutect2, varscan2
- LRP1B | c.918G>T p.R306= | Silent (SNP) | VAF 40/199 reads (20%) | catalogued as rs763270918; called by muse, mutect2, varscan2
- MIS18A | c.9C>A p.G3= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as COSV99267155; called by mutect2, varscan2
- MUC4 | c.14496C>T p.R4832= (on ENST00000463781 / NM_018406.7; = p.R596= on NM_004532.6) | Silent (SNP) | VAF 36/412 reads (9%) | called by muse, mutect2
- MYO18B | c.4422C>G p.V1474= | Silent (SNP) | VAF 71/198 reads (36%) | catalogued as rs772801891; called by muse, mutect2, varscan2
- NCAPG2 | c.1275G>A p.G425= | Silent (SNP) | VAF 35/74 reads (47%) | called by muse, mutect2, varscan2
- NIPSNAP1 | c.447G>T p.L149= | Silent (SNP) | VAF 37/144 reads (26%) | called by muse, mutect2, varscan2
- NPHP3 | c.2466A>G p.Q822= | Silent (SNP) | VAF 95/204 reads (47%) | catalogued as rs956903200; called by muse, mutect2, varscan2
- NUTM2B | c.1782A>G p.P594= | Silent (SNP) | VAF 22/226 reads (10%) | called by mutect2, varscan2
- OR51B2 | c.876C>T p.I292= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as COSV60916985; called by muse, mutect2
- OR52I2 | c.864C>A p.S288= | Silent (SNP) | VAF 80/283 reads (28%) | called by muse, mutect2, varscan2
- PCDH11X | c.2631C>A p.S877= | Silent (SNP) | VAF 102/256 reads (40%) | called by muse, varscan2
- PCDHA11 | c.2271G>T p.V757= | Silent (SNP) | VAF 70/257 reads (27%) | called by muse, mutect2, varscan2
- PCDHA3 | c.1854G>T p.A618= | Silent (SNP) | VAF 74/216 reads (34%) | catalogued as rs1554122551, COSV63538759; called by muse, mutect2, varscan2
- PDE11A | c.2737C>T p.L913= | Silent (SNP) | VAF 128/452 reads (28%) | called by muse, mutect2, varscan2
- PLXNA4 | c.3750C>T p.I1250= | Silent (SNP) | VAF 76/234 reads (32%) | called by muse, mutect2, varscan2
- PPP6C | c.774T>G p.A258= | Silent (SNP) | VAF 62/259 reads (24%) | called by muse, mutect2, varscan2
- RAB8A | c.276C>T p.N92= | Silent (SNP) | VAF 33/120 reads (28%) | catalogued as rs1470271434; called by muse, mutect2, varscan2
- SHE | c.1084C>A p.R362= | Silent (SNP) | VAF 41/246 reads (17%) | called by muse, mutect2, varscan2
- SLC14A2 | c.2394G>A p.T798= | Silent (SNP) | VAF 36/125 reads (29%) | catalogued as rs553345738, COSV54910905; called by muse, varscan2
- SLC18A3 | c.99C>A p.R33= | Silent (SNP) | VAF 24/60 reads (40%) | called by muse, mutect2, varscan2
- SLC1A2 | c.111G>T p.L37= | Silent (SNP) | VAF 49/191 reads (26%) | called by muse, mutect2, varscan2
- SLC3A1 | c.1761T>C p.D587= | Silent (SNP) | VAF 103/298 reads (35%) | called by muse, mutect2, varscan2
- SLX4 | c.4719G>T p.V1573= | Silent (SNP) | VAF 42/280 reads (15%) | called by muse, mutect2, varscan2
- SPATA5L1 | c.429G>T p.P143= | Silent (SNP) | VAF 134/420 reads (32%) | called by muse, mutect2, varscan2
- TAP2 | c.987G>T p.G329= | Silent (SNP) | VAF 117/368 reads (32%) | called by muse, mutect2, varscan2
- TMEM187 | c.333C>G p.A111= | Silent (SNP) | VAF 33/48 reads (69%) | called by muse, mutect2, varscan2
- TRMT5 | c.1074C>T p.D358= | Silent (SNP) | VAF 119/236 reads (50%) | called by muse, mutect2, varscan2
- UNC13C | c.606C>T p.T202= | Silent (SNP) | VAF 18/154 reads (12%) | catalogued as COSV99512691; called by muse, mutect2
- VWDE | c.402T>C p.S134= | Silent (SNP) | VAF 37/179 reads (21%) | called by muse, mutect2, varscan2
- WNT11 | c.228C>A p.V76= | Silent (SNP) | VAF 111/309 reads (36%) | called by muse, mutect2, varscan2
- ZNF208 | c.1863C>A p.V621= | Silent (SNP) | VAF 58/266 reads (22%) | catalogued as COSV68103389; called by muse, varscan2
- ZNF232 | c.159A>T p.G53= | Silent (SNP) | VAF 92/352 reads (26%) | catalogued as rs780593744; called by muse, mutect2, varscan2
- ZNF491 | c.1113T>C p.H371= | Silent (SNP) | VAF 17/49 reads (35%) | called by muse, mutect2, varscan2
- ABCA13 | c.14744+8902T>C | Intron (SNP) | VAF 4/39 reads (10%) | catalogued as rs1313087756; called by muse, mutect2
- ABCC13 | n.4029G>C | RNA (SNP) | VAF 84/167 reads (50%) | called by muse, mutect2, varscan2
- AC107023.1 | n.25+747C>A | Intron (SNP) | VAF 26/76 reads (34%) | catalogued as rs1011310049; called by muse, mutect2
- AC107023.1 | n.25+498C>G | Intron (SNP) | VAF 26/79 reads (33%) | called by muse, varscan2
- ADCYAP1 | chr18:904457 G>T | 5'Flank (SNP) | VAF 13/122 reads (11%) | called by muse, mutect2, varscan2
- APBB3 | c.49+15G>A | Intron (SNP) | VAF 14/79 reads (18%) | called by muse, mutect2, varscan2
- ASB18 | c.206-82C>G | Intron (SNP) | VAF 66/145 reads (46%) | called by muse, mutect2, varscan2
- BEST1 | c.1739+152T>A | Intron (SNP) | VAF 7/20 reads (35%) | catalogued as rs760535761; called by mutect2, varscan2
- CACNA2D1 | c.879+9820T>A | Intron (SNP) | VAF 32/144 reads (22%) | called by muse, mutect2, varscan2
- CDH9 | c.999+118C>A | Intron (SNP) | VAF 96/214 reads (45%) | catalogued as rs764707569; called by muse, mutect2, varscan2
- CDH9 | c.999+117C>A | Intron (SNP) | VAF 96/214 reads (45%) | called by muse, mutect2, varscan2
- ELMO1 | c.243+21G>A | Intron (SNP) | VAF 34/117 reads (29%) | catalogued as rs1442822034; called by muse, mutect2, varscan2
- FCF1 | c.*24G>T | 3'UTR (SNP) | VAF 36/77 reads (47%) | called by muse, mutect2, varscan2
- GABRE | c.1137+123T>C | Intron (SNP) | VAF 23/137 reads (17%) | called by muse, mutect2, varscan2
- IQCE | c.1969+49G>A | Intron (SNP) | VAF 21/55 reads (38%) | called by muse, mutect2, varscan2
- MBD5 | c.*21C>T | 3'UTR (SNP) | VAF 40/342 reads (12%) | catalogued as rs748197238, COSV101289960; called by muse, mutect2, varscan2
- MSC-AS1 | n.512G>T | RNA (SNP) | VAF 55/192 reads (29%) | called by muse, mutect2, varscan2
- Metazoa_SRP | chr15:62246537 T>C | 5'Flank (SNP) | VAF 43/108 reads (40%) | called by muse, mutect2, varscan2
- NEB | c.8889+3628G>A | Intron (SNP) | VAF 21/525 reads (4%) | called by muse, mutect2
- PDE1A | c.*28G>A | 3'UTR (SNP) | VAF 32/95 reads (34%) | catalogued as rs1260340871; called by muse, mutect2, varscan2
- PLCB1 | c.3423+11853C>A | Intron (SNP) | VAF 105/360 reads (29%) | called by muse, mutect2, varscan2
- PLEKHM1P1 | n.1225A>G | RNA (SNP) | VAF 42/162 reads (26%) | called by muse, mutect2, varscan2
- RNF145 | c.-40+1442A>G | Intron (SNP) | VAF 14/320 reads (4%) | called by muse, mutect2
- RPP38 | chr10:15096415 T>C | 5'Flank (SNP) | VAF 11/37 reads (30%) | catalogued as rs746044087; called by muse, mutect2, varscan2
- SGIP1 | c.1571-64A>G | Intron (SNP) | VAF 59/134 reads (44%) | catalogued as COSV52775668; called by muse, mutect2, varscan2
- SKIV2L | c.-2G>C | 5'UTR (SNP) | VAF 8/65 reads (12%) | called by muse, mutect2, varscan2
- SLC10A7 | c.435+103A>G | Intron (SNP) | VAF 18/42 reads (43%) | catalogued as COSV53882989; called by muse, varscan2
- SMARCAD1 | c.*211A>T | 3'UTR (SNP) | VAF 31/56 reads (55%) | called by muse, mutect2, varscan2
- SMG1P6 | n.1455G>C | RNA (SNP) | VAF 32/355 reads (9%) | called by muse, mutect2, varscan2
- SPATA31C2 | n.1875A>G | RNA (SNP) | VAF 66/249 reads (27%) | called by muse, mutect2, varscan2
- SRM | c.*9G>T | 3'UTR (SNP) | VAF 12/20 reads (60%) | called by mutect2, varscan2
- TCF20 | c.*99C>T | 3'UTR (SNP) | VAF 18/64 reads (28%) | called by muse, mutect2, varscan2
- VIM | c.564-33C>G | Intron (SNP) | VAF 29/298 reads (10%) | catalogued as rs778097133; called by muse, mutect2
- Y_RNA | chr7:23491108 A>C | 3'Flank (SNP) | VAF 39/153 reads (25%) | called by muse, mutect2, varscan2
- ZIC4 | c.-15-1243T>A | Intron (SNP) | VAF 47/152 reads (31%) | called by muse, mutect2, varscan2
- ZMAT4 | c.103-19048C>A | Intron (SNP) | VAF 22/100 reads (22%) | called by muse, mutect2, varscan2
